Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6822, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6822-01A (Primary Tumor).

Department of Cancer Pathology (cito)

original

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – stomach**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Gastric cancer, partial resection.**

Examination performed on:

Macroscopic description:

Specimen consisting of the stomach, after having been excised along the greater curvature, sized 14.5 x 10.5 cm with the omentum sized 9 x 5 and 18 x 4.5 cm.

A cauliflower-shaped and ulcerous tumour sized 8 x 7.5 x 4 cm in the region of the lesser curvature . Distance from the proximal boundary 7 cm, from distal boundary, 0 cm.

Microscopic description:

Adenocarcinoma tubulopapillare G2.

The tumour infiltrates through the full thickness of the stomach wall, perigastric fat tissue, blood vessels.

Neoplastic spreads over the distal incision line. Proximal line and the omentum clear of cancerous infiltration.

Outside the tumour: mucous membrane showing symptoms of chronic inflammation with features of focal intestinal metaplasia.

Lymphonodulitis reactiva No VII.

Histopathological Diagnosis:

Adenocarcinoma tubulopapillare ventriculi. Tubulopapillar adenocarcinoma of the stomach.

G2, pT2b, pNO typus intestinalis sec.

Intestinal

Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

HER2 protein stained with HercepTest™ by DAKO.

Positive reaction in invasive cancerous cells (Score = 0)

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 4a214571-c410-4c1d-b963-86e74a66e3d7 (TCGA-D7-6822.B740D000-B1D3-4F11-89E5-8BB36470FAE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).